Surgical pathology report (de-identified scan), TCGA case TCGA-FF-A7CX, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma), tissue source site SingHealth, specimen TCGA-FF-A7CX-01A (Primary Tumor).

Patient Results

Requested By:

Histopathology Report

Biopsy No:

Final

Received Date/Time

Final

Reporting Information

Date/Time :

Final

Histopathologist :

Laboratory :

Consultant-In-Charge

Final

Submitting Physician

Final

Histopathology Report

Final

DIAGNOSIS

LEFT PERITHYROIDAL SOFT TISSUE; INCISIONAL BIOPSY:
DIFFUSE LARGE B-CELL LYMPHOMA.

GROSS DESCRIPTION

Received fresh is an irregular piece of tissue labelled as "left thyroid region" measuring 1.3 x 1.2 x 0.7cm, which is divided into 4 pieces. One piece measuring 1.1 x 0.7 x 0.3cm is snap-frozen for storage.

Subsequently received in formalin and labelled with patient's details is a specimen designated as 'left thyroid region'. It consists of two pieces of pinkish, fleshy tissue measuring 1 x 0.7 x 0.6 cm and 1 x 0.8 x 0.4 cm with minimal amounts of surrounding fatty tissue, submitted entirely. (A1; no reserve).

MICROSCOPIC DESCRIPTION

Histology shows predominantly extrathyroidal connective tissue harbouring a diffuse, patternless infiltrate of lymphomatous cells, where best preserved appearing medium-to-large, with "open" vesicular nuclei and discernible nucleoli, enclosed in moderate amounts of cytoplasm, sometimes with a plasmacytoid nuance, infiltrating in-between residual skeletal muscle fibres and adipocytes. No epithelial malignancy, granulomas or necrosis is seen.

The lymphomatous infiltrate recapitulates its CD20/bcl-6/MUM.1 and bcl-2(+), reactive CD3(+) T-lymphocytes, which are scattered and few, hence excluding Burkitt lymphoma in conjunction with a cell proliferation fraction that falls well below 100% (approximately 70-80% by Ki-67 immunolabelling), despite currently-discernible coexpression of germinal centre-associated CD10, albeit variable and mostly weak. In addition, the lymphomatous cells coexpress IgGc-associated CD79a. Negativity for cyclin D1, except for physiological expression in scattered histiocytic and activated endothelial nuclei, excludes a transformed mantle cell lymphoma. Negativity for terminal deoxynucleotidyl transferase and pancytokeratin (MNF116) respectively exclude lymphoblastic neoplasia and carcinoma, in the presence of working external positive controls.

Pathologist :

ICD-O-3

Lymphoma, diffuse large B cell 9680/3

Site Neck, soft tissue 149.0

8/26/13

Case is (Type):		

Printed from:

End of Report

Page: 1 of 1

Source: NCI Genomic Data Commons file 3b24d8b1-e262-47d9-826d-528d53346b6f (TCGA-FF-A7CX.7CABE1CC-F2F2-4B54-9568-DCFE2065C86B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).